Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A0DB, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A0DB-01A (Primary Tumor).

[page 1 of 4]
Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 10/27/11

SPECIMEN

- A. Sentinel node #1 right axilla, hot and blue, count of 300
- B. Sentinel node #2 palpable right axilla, not hot and not blue.
- C. Sentinel node #3, hot and blue, count of 70 right axilla.
- D. Segmental mastectomy right breast, single long lateral, double long anterior.
- E. Tissue medial to segmental mastectomy right breast. Stitch is new medial right margin.

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right breast cancer, clinical stage 2A carcinoma of right breast.

FROZEN SECTION DIAGNOSIS

- A. Two lymph nodes negative for metastatic disease.
- B. Single lymph node negative for metastatic disease.
- C. Single lymph node negative for metastatic disease.

GROSS DESCRIPTION

A. Part A is received fresh for frozen section labeled "sentinel node #2 right axilla". It consists of a portion of lymph node-bearing hemorrhagic adipose tissue measuring 2 x 1.7 x

0.5 cm. Within the fat two lymph nodes are present. The smaller measures 0.6 x 0.3 x 0.3 cm. On section it is dark blue and soft. The larger node measures 1.3 x 0.5 x 0.5 cm. On section it is mostly

fatty with an area of dark blue discoloration. Each node is entirely submitted in one block for frozen section.

B. Received fresh for frozen section labelled "sentinal node #2 palpable right axilla." It consists of a single discrete pink-tan nodule measuring 0.8 x 0.7 x 0.5 cm. On section it is homogenous soft and tan. It is bisected and all submitted in one block for frozen section.

C. Received fresh for frozen section labelled "sentinel node #3 right axilla." It consists of a single pink-blue nodule measuring 0.3 cm in diameter all submitted for frozen section

[page 2 of 4]
GROSS DESCRIPTION

in one block.

D. Received fresh for tissue procurement as "segmental mastectomy right breast." It consists of a portion of fibroadipose tissue measuring 6.2 x 5.5 x 3.8 cm. Sutures are present for orientation. The superior margin is painted orange, inferior margin yellow, anterior margin green, lateral margin blue, medial margin red and posterior margin black. On the surface of the anteroinferior portion there is a possible piece of skin measuring 1

x 0.6 cm. The surface of this possible skin fragment is painted red. On sectioning, the specimen, centrally, there is a biopsy cavity containing amorphous hemorrhagic debris and at least 1 rice-like foreign object. Surrounding this 1 cm cavity is an area of firm dull tan induration consistent with tumor. This tumor does not grossly approximate margins and comes apparently closest to the posterior margin. A portion of this tumor is taken for tissue procurement. The tumor measures 2.5 cm in greatest dimension. Representative sections are submitted following fixation.

BLOCK SUMMARY: D1-D2 - orange end of the specimen, D3-D4 - yellow end of the specimen, D5-D20 - biopsy cavity with adjacent margins. RS-20.

E. The specimen is received unfixed labelled "tissue medial to

segmental mastectomy right breast." It consists of a portion of fibroadipose tissue measuring 4.5 x 1.7 x 1 cm. A suture is present on one surface. The surface with the suture is painted orange as the opposite surface is painted black. The tissue is grossly unremarkable. AS-1.

BLOCK SUMMARY: Tissue submitted from one end to the other and submitted in cassettes E1-E5. AS-5.

[page 3 of 4]
MICROSCOPIC DESCRIPTION

Invasive carcinoma:

Histologic type: Ductal

Histologic grade: Moderately differentiated

Overall grade: 2

Architectural score: 2-3

Nuclear score: 2-3

Mitotic score: 1

Greatest dimension (pT): 2.5 cm, pT2

Specimen margins: Invasive carcinoma extends to 2 mm from the anterior margin of excision.

Vessel invasion: Not identified

Calcification: Multifocal calcifications are identified within the invasive carcinoma.

Ductal carcinoma in situ:

Histologic pattern: Cribriform

Nuclear grade: 2

Central necrosis: Focally present

% DCIS of total tumor (if mixed): Less than 25%

Extensive intraductal component (present/absent): Present

Specimen margins: Ductal carcinoma in situ is present 0.5 mm from the anterior margin of excision.

Calcification: Present

Description of non-tumorous breast: Fibrocystic changes with mild to florid ductal hyperplasia and microcalcifications identified associated with benign breast epithelium. Skin with central ulceration, inflammation and reactive changes.

Comments: The sentinel lymph nodes are serially sectioned and stain

with keratin immunohistochemistry. Within the invasive carcinoma focal perineural invasion by tumor is identified. A p63 stain is performed on several blocks to evaluate DCIS.

[page 4 of 4]
MICROSCOPIC DESCRIPTION

Lymph nodes:

Number of positive nodes of total: Zero, 0/4

pN: pN0

Distant metastasis (pM): pMX

14x3, 15x1, 20x4, 4x5

DIAGNOSIS

A. Lymph node, sentinel node #1, right axilla, excision -- Two lymph

nodes negative for metastatic carcinoma (0/2).

B. Lymph node, sentinel node #2, excision -- One lymph node negative

for metastatic carcinoma (0/1).

C. Lymph node, sentinel node #3, excision -- One lymph node negative

for metastatic carcinoma (0/1).

D. Breast, right, segmental mastectomy -- Invasive moderately ductal

adenocarcinoma and ductal carcinoma in situ (see tumor

characteristics in the mastectomy template in the microscopic description).

E. Breast, tissue medial to segmental mastectomy, excision --

Fibrocystic changes with mild to moderate ductal hyperplasia and microcalcifications identified associated with benign breast epithelium.

--

M.D. (Electronic Signature)

--- End of Report ---

Source: NCI Genomic Data Commons file e2897daa-b9a7-4792-a8dc-94844173996e (TCGA-A7-A0DB.511CB4C5-FCEE-4EC4-98A4-4DD32ECA83C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).